Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3326, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3326-01A (Primary Tumor).

[page 1 of 2]
Laboratory Patient: [REDACTED]
Print Date/Time: [REDACTED]

Surgical Pathology

Histopathological Examination

Path#: [REDACTED]
Collected: [REDACTED] Received: [REDACTED] Complete: [REDACTED]

Pre-Op Diagnosis : Rt Renal Cell Carcinoma
Order Physician : [REDACTED] MD
Specimens : Kidney, Right
Frozen Diagnosis : Block# : A-1
Re-Ex? : no
FS-Diag : Renal cell carcinoma
Comment : none
Consult by: none

Report

: GROSS EXAMINATION.

The specimen is received in a container labeled with the name of the patient and labeled as kidney, right. The specimen consists of a kidney and perinephric fat which measures 20 x 11 x 6 cm and weighs 730 g. There is a 3.5 x 0.3 cm segment of ureter attached. The specimen is bivalved which reveals a golden yellow mass which measures 2.7 x 2.5 x 2.4 cm. The mass is located at the lower pole. A frozen section is performed on the mass.

FROZEN SECTION DIAGNOSIS: Renal cell carcinoma. [REDACTED]

The ureteral margin and vascular margins are submitted in block two. The ureteropelvic junction is submitted in block two. The lesion pushes against the capsular membrane but does not appear to involve it. The mass and capsule are sampled in block's four through six. The capsule strips easily from the surface of the kidney. No additional areas of lesion are grossly identified. The cortex averages 1.5 cm thickness. The calices are not dilated. Representative sections of normal appearing kidney are submitted in block's seven and eight. The perinephric fat is examined for adrenal gland. No adrenal glands grossly identified. Representative sections are submitted. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

KIDNEY: Nephrectomy
SPECIMEN TYPE: Radical nephrectomy.
LATERALITY: Right.

[page 2 of 2]
TUMOR SITE: Lower pole.
FOCALITY: Unifocal.
TUMOR SIZE (LARGEST TUMOR IF MULTIPLE): 2.7 x 2.5 x 2.4 cm.
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney.
HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma.
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): G1: Fuhrman
nuclear Grade I.
EXTENT OF INVASION
PRIMARY TUMOR (PT): pT1a: Tumor 4.0 cm or less in greatest
dimension, limited to kidney.
REGIONAL LYMPH NODES (PN): pNX: Cannot be assessed
DISTANT METASTASIS (PM): pMX: Cannot be assessed
MARGINS: Uninvolved by invasive carcinoma.
ADRENAL GLAND: Present.
VENOUS (LARGE VESSEL) INVASION (V): Absent.
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent.
ADDITIONAL PATHOLOGIC FINDINGS: Mild nonspecific chronic
pyelitis.
Intradepartmental consultation obtained.
[T-71000 M-83103 189.0 P3-44070]

[REDACTED]
Pathologist
[REDACTED]
[REDACTED]

Electronically Signed by:
[REDACTED]

Source: NCI Genomic Data Commons file af584cd8-0748-466d-9ff6-3719d265e570 (TCGA-A3-3326.B0E5378C-8128-4CA7-960B-028E1921A836.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).